CCDI case PBCAMK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a4468173-6288-43c3-b795-e1d202689c9d

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 6.5 years (2,356 days).

Biospecimens (3 samples)
- Sample 0DMN18: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMN1P: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMN2C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
